Somatic mutation profile of tumor specimen MP2PRT-PAVNRM-TBP1-A (aliquot MP2PRT-PAVNRM-TBP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVNRM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (852 days).
Specimen MP2PRT-PAVNRM-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 133010df-21b2-416b-8838-758d0e6b39c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVNRM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVNRM-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6d52e2a-e946-41e4-8f08-581e67b4426f

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 89/363 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BCL11B | c.784C>T p.R262W (on ENST00000357195 / NM_001282237.2; = p.R191W on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 165/804 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763799880; called by muse, mutect2, varscan2
- SPATC1 | c.967C>T p.P323S | Missense Mutation (SNP) | VAF 130/442 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV66298951; called by mutect2, varscan2
- TFDP1 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 89/342 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750890106, COSV64739777, COSV64740643; called by muse, mutect2, varscan2
- CNOT6L | c.1108G>A p.V370M (on ENST00000504123 / NM_001286790.2; = p.V365M on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/402 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- HCFC2 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 67/299 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SBK3 | c.877A>C p.T293P | Missense Mutation (SNP) | VAF 148/570 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- TNXB | c.10301C>T p.T3434I (on ENST00000647633; = p.T3187I on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 194/855 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- GRAMD1B | c.1599C>T p.S533= | Silent (SNP) | VAF 62/210 reads (30%) | catalogued as rs759545068; called by muse, varscan2
- IGHA1 | chr14:105704540 C>T | 3'Flank (SNP) | VAF 73/565 reads (13%) | called by muse, mutect2, varscan2
